Somatic mutation profile of cancer-model specimen HCM-CSHL-0900-C54-85B (3D Organoid, passage 9; aliquot HCM-CSHL-0900-C54-85B-01D-A88H-36), derived from the primary tumor of HCMI case HCM-CSHL-0900-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC2; FIGO stage: Stage IIIC2; Tumor grade: G3.
Specimen HCM-CSHL-0900-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4aedcff-4b6c-4253-b01a-db8710e2fe96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0900-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0900-C54-11A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/692e0283-c3bb-4814-aea5-a3c8396dc9a0

The open-access MAF lists 120 somatic variants for this specimen: 89 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 28, Frame Shift Del 6, Intron 3, Nonsense Mutation 3, In Frame Del 2, Splice Region 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLCN1 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 192/331 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80356704, CM990364; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 224/224 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.2965G>C p.V989L | Missense Mutation (SNP) | VAF 131/615 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV64673157; called by muse, mutect2, varscan2
- ABCB8 | c.164G>A p.R55H (on ENST00000297504 / NM_001282291.2; = p.R38H on NM_007188.5) | Missense Mutation (SNP) | VAF 236/375 reads (63%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs528488908; called by muse, mutect2, varscan2
- AHDC1 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 151/316 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs754239206, COSV99898937; called by muse, mutect2, varscan2
- BRINP3 | c.1879A>C p.I627L | Missense Mutation (SNP) | VAF 135/388 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV66526989; called by mutect2, varscan2
- CACNA1G | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 299/844 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV61734485; called by muse, mutect2, varscan2
- CCDC168 | c.12253A>G p.T4085A | Missense Mutation (SNP) | VAF 25/413 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as rs963695672; called by muse, mutect2
- CCDC39 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1470125398, COSV56483008; called by muse, mutect2, varscan2
- CDC40 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs769950440; called by muse, mutect2, varscan2
- CNGB3 | c.326A>T p.E109V | Missense Mutation (SNP) | VAF 65/514 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV60684645; called by muse, mutect2, varscan2
- COL5A1 | c.3369C>T p.G1123= | Splice Region (SNP) | VAF 119/258 reads (46%) | catalogued as rs546229885; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CTNND2 | c.2678G>A p.G893D | Missense Mutation (SNP) | VAF 227/387 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58934561; called by muse, mutect2, varscan2
- CYP2C9 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 117/275 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs12414460, CM1412015; called by muse, mutect2, varscan2
- DNHD1 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 310/311 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1413322304, COSV54438439; called by muse, mutect2, varscan2
- DQX1 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV52046107; called by muse, mutect2, varscan2
- FAT1 | c.4194C>G p.Y1398* | Nonsense Mutation (SNP) | VAF 97/222 reads (44%) | catalogued as COSV71676268; called by muse, mutect2, varscan2
- FBN1 | c.6323G>T p.R2108L | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as rs762659907; called by muse, mutect2, varscan2
- HERC4 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99517241; called by muse, mutect2, varscan2
- JAML | c.649G>A p.G217S (on ENST00000356289 / NM_001098526.2; = p.G207S on NM_153206.3) | Missense Mutation (SNP) | VAF 92/224 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs772971972, COSV99409283; called by muse, varscan2
- KIF13A | c.5250G>C p.L1750F | Missense Mutation (SNP) | VAF 105/703 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as COSV99035620; called by muse, mutect2
- LY6G5C | c.659G>C p.R220T (on ENST00000375863; = p.R145T on NM_025262.3) | Missense Mutation (SNP) | VAF 273/574 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1372679813; called by muse, mutect2, varscan2
- NFKBIZ | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 128/551 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs558651793; called by muse, mutect2, varscan2
- NLRP14 | c.2602C>A p.Q868K | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748848609; called by muse, mutect2
- NOM1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 260/378 reads (69%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51979717; called by muse, mutect2, varscan2
- OLFML2A | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs780409580; called by muse, mutect2
- OPRL1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 208/678 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs772654648; called by muse, varscan2
- OPRM1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 100/239 reads (42%) | catalogued as rs200512398, COSV100000556; called by muse, varscan2
- OR14I1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 243/431 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs758276680, COSV100700410; called by muse, mutect2, varscan2
- OR6N2 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100210221, COSV59411056; called by muse, mutect2, varscan2
- PIK3R1 | c.1356_1358dup p.N453dup (on ENST00000521381 / NM_181523.3; = p.N183dup on NM_181504.4) | In Frame Ins (INS) | VAF 37/88 reads (42%) | catalogued as COSV57140765, COSV99073794; called by mutect2, pindel, varscan2
- POTEJ | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 59/298 reads (20%) | catalogued as COSV68641617; called by muse, mutect2, varscan2
- RPUSD3 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 177/502 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV100047410, COSV59613682; called by muse, mutect2, varscan2
- RUSC1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs202238389; called by muse, varscan2
- SALL1 | c.2967_2968dup p.F990Sfs*56 | Frame Shift Ins (INS) | VAF 83/212 reads (39%) | catalogued as rs1420114354; called by mutect2, pindel, varscan2
- SCAPER | c.2027G>C p.R676P | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57756096; called by muse, mutect2, varscan2
- SLITRK5 | c.1028G>C p.R343P | Missense Mutation (SNP) | VAF 142/461 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV61522033, COSV61525099; called by muse, mutect2, varscan2
- SOX1 | c.703_723del p.H235_H241del | In Frame Del (DEL) | VAF 116/674 reads (17%) | catalogued as rs1277713927; called by mutect2, varscan2
- TLNRD1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 177/363 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1415973078; called by muse, mutect2, varscan2
- TMC2 | c.2118C>G p.S706R | Missense Mutation (SNP) | VAF 227/322 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1568526680; called by muse, mutect2, varscan2
- TMEM132D | c.3079G>T p.G1027W | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV67159216; called by muse, mutect2, varscan2
- TP63 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53203752, COSV99287706; called by muse, mutect2, varscan2
- USP11 | c.2653C>T p.R885C (on ENST00000218348; = p.R842C on NM_001371072.1) | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1183417765; called by muse, mutect2
- ZFHX4 | c.8654del p.S2885Tfs*20 | Frame Shift Del (DEL) | VAF 230/864 reads (27%) | catalogued as COSV51498775; called by mutect2, pindel, varscan2
- ZNF616 | c.618A>G p.I206M | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs748000428; called by muse, mutect2
- AADACL4 | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 27/744 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); called by muse, mutect2
- ACAP3 | c.2009_2029del p.L670_A676del | In Frame Del (DEL) | VAF 197/1093 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.1844G>T p.C615F | Missense Mutation (SNP) | VAF 32/924 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRB1 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 250/1294 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADGRB3 | c.2545A>G p.T849A | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKS6 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 163/341 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOH | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 76/543 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ARL3 | c.351T>G p.S117R | Missense Mutation (SNP) | VAF 123/230 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ASPM | c.3694G>T p.A1232S | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ATP13A5 | c.2676C>T p.I892= | Splice Region (SNP) | VAF 75/255 reads (29%) | called by muse, mutect2, varscan2
- CACNA1A | c.3169G>C p.D1057H | Missense Mutation (SNP) | VAF 204/1206 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- COX7C | c.171A>T p.R57S | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSN3 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- DNMT3A | c.1853A>G p.D618G | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- EPOP | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 258/1259 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FANCL | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FLT4 | c.3558G>A p.M1186I | Missense Mutation (SNP) | VAF 136/466 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- GMPS | c.198_204del p.E66Dfs*42 | Frame Shift Del (DEL) | VAF 68/363 reads (19%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.9280G>A p.E3094K | Missense Mutation (SNP) | VAF 107/496 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GPR152 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSD11B2 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 229/229 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- JUND | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 76/894 reads (9%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.558); called by muse, mutect2
- KCNF1 | c.103G>C p.V35L | Missense Mutation (SNP) | VAF 60/932 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.22); called by muse, mutect2
- KMT2D | c.3768_3777del p.L1257Vfs*70 | Frame Shift Del (DEL) | VAF 64/602 reads (11%) | called by mutect2, pindel
- MMP9 | c.1124C>A p.T375N | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEXN | c.967_971del p.E323* | Frame Shift Del (DEL) | VAF 38/194 reads (20%) | called by pindel, varscan2
- OR2W3 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 86/414 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PDZD3 | c.1643C>G p.S548C (on ENST00000531114; = p.S468C on NM_024791.4) | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- PHACTR1 | c.509_510del p.S170Yfs*4 | Frame Shift Del (DEL) | VAF 38/365 reads (10%) | called by pindel, varscan2
- PMEPA1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 201/693 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PSME4 | c.2861C>T p.T954I | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- PTCH2 | c.1946A>C p.E649A | Missense Mutation (SNP) | VAF 118/405 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- QSER1 | c.5110G>A p.E1704K (on ENST00000399302; = p.E1833K on NM_001076786.3) | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- SH3RF1 | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 125/576 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC25A16 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC6A2 | c.1791G>C p.E597D | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SWSAP1 | c.364G>T p.A122S (on ENST00000312423; = p.A143S on NM_175871.4) | Missense Mutation (SNP) | VAF 76/1304 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.929); called by muse, mutect2
- TICRR | c.3097T>A p.S1033T | Missense Mutation (SNP) | VAF 125/257 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TMEM33 | c.527T>C p.F176S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTN | c.63908C>T p.P21303L (on ENST00000591111; = p.P13879L on NM_003319.4) | Missense Mutation (SNP) | VAF 82/213 reads (38%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGGT2 | c.3922_3923del p.R1308Dfs*11 | Frame Shift Del (DEL) | VAF 60/392 reads (15%) | called by pindel, varscan2
- WASHC5 | c.1146C>G p.D382E | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ZNF536 | c.2874A>C p.K958N | Missense Mutation (SNP) | VAF 54/1064 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- ZSWIM5 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 234/745 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ADAM9 | c.636G>A p.R212= | Silent (SNP) | VAF 17/600 reads (3%) | called by muse, mutect2
- ALPL | c.99G>A p.A33= | Silent (SNP) | VAF 80/196 reads (41%) | catalogued as rs772424729, COSV66379760; ClinVar: likely benign; called by muse, mutect2, varscan2
- APBA1 | c.288G>C p.V96= | Silent (SNP) | VAF 57/600 reads (10%) | catalogued as rs1426114797; called by muse, mutect2
- ARMC2 | c.324G>A p.E108= | Silent (SNP) | VAF 106/214 reads (50%) | called by muse, mutect2, varscan2
- BUB1 | c.1131C>T p.A377= | Silent (SNP) | VAF 230/675 reads (34%) | called by muse, mutect2, varscan2
- CELSR3 | c.651C>A p.G217= | Silent (SNP) | VAF 181/978 reads (19%) | catalogued as COSV99373523; called by muse, mutect2, varscan2
- CNOT11 | c.360C>T p.S120= | Silent (SNP) | VAF 197/862 reads (23%) | called by muse, mutect2, varscan2
- COLEC12 | c.15C>T p.F5= | Silent (SNP) | VAF 82/624 reads (13%) | catalogued as rs776065087, COSV68370750; called by muse, mutect2, varscan2
- CRELD1 | c.114T>C p.S38= | Silent (SNP) | VAF 146/535 reads (27%) | called by muse, mutect2, varscan2
- DNAH12 | c.5706G>A p.V1902= (on ENST00000351747; = p.V1921= on NM_001366028.2) | Silent (SNP) | VAF 93/312 reads (30%) | called by muse, mutect2, varscan2
- DOCK6 | c.4881G>A p.V1627= | Silent (SNP) | VAF 230/1758 reads (13%) | called by muse, mutect2, varscan2
- DRD1 | c.342C>G p.L114= | Silent (SNP) | VAF 87/353 reads (25%) | catalogued as rs771244904; called by muse, mutect2, varscan2
- FBRSL1 | c.1824G>A p.K608= | Silent (SNP) | VAF 76/233 reads (33%) | called by muse, mutect2, varscan2
- FEN1 | c.633G>A p.R211= | Silent (SNP) | VAF 443/443 reads (100%) | called by muse, mutect2, varscan2
- FGF6 | c.153G>C p.S51= | Silent (SNP) | VAF 359/360 reads (100%) | called by muse, mutect2, varscan2
- HNRNPU | c.90C>G p.L30= | Silent (SNP) | VAF 117/433 reads (27%) | called by muse, mutect2, varscan2
- ITGAL | c.756G>A p.R252= | Silent (SNP) | VAF 228/351 reads (65%) | called by muse, mutect2, varscan2
- MAP1S | c.2418G>A p.A806= | Silent (SNP) | VAF 66/910 reads (7%) | called by muse, mutect2
- RBM42 | c.222G>T p.A74= | Silent (SNP) | VAF 156/904 reads (17%) | catalogued as COSV52547148, COSV52550341; called by muse, mutect2, varscan2
- RHPN2 | c.6C>T p.T2= | Silent (SNP) | VAF 144/1254 reads (11%) | called by muse, mutect2, varscan2
- RTTN | c.4200T>C p.C1400= | Silent (SNP) | VAF 110/436 reads (25%) | called by muse, mutect2, varscan2
- SLC16A5 | c.1212C>T p.F404= | Silent (SNP) | VAF 108/1154 reads (9%) | catalogued as rs774323424; called by muse, mutect2
- SLC22A14 | c.1113C>T p.F371= | Silent (SNP) | VAF 134/401 reads (33%) | catalogued as COSV56196130; called by muse, mutect2, varscan2
- SNAPC4 | c.1404A>C p.I468= | Silent (SNP) | VAF 75/377 reads (20%) | called by muse, mutect2, varscan2
- SPATA20 | c.1179G>A p.Q393= (on ENST00000356488 / NM_001258372.1; = p.Q409= on NM_022827.4) | Silent (SNP) | VAF 115/620 reads (19%) | catalogued as rs1372279549; called by muse, mutect2, varscan2
- TBX15 | c.1647C>T p.N549= (on ENST00000369429 / NM_001330677.2; = p.N443= on NM_152380.3) | Silent (SNP) | VAF 240/725 reads (33%) | catalogued as COSV52874650, COSV99253681; called by muse, mutect2, varscan2
- TMEM63B | c.2163C>T p.I721= | Silent (SNP) | VAF 26/549 reads (5%) | catalogued as rs1353250713, COSV99441797; called by muse, mutect2
- ZNF436 | c.1254C>T p.Y418= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as rs199807996; called by muse, mutect2, varscan2
- CDH11 | c.1895-573G>C | Intron (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3554G>A | Intron (SNP) | VAF 87/750 reads (12%) | called by muse, varscan2
- MANBA | c.2554-1098C>T | Intron (SNP) | VAF 47/271 reads (17%) | called by muse, mutect2, varscan2
